Somatic mutation profile of tumor specimen TCGA-AA-3695-01A (aliquot TCGA-AA-3695-01A-01W-0900-09) from TCGA case TCGA-AA-3695, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IV; Age at diagnosis: 63.4 years (23,164 days).
Specimen TCGA-AA-3695-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e35e404d-2ab8-4a2e-b31e-db8b80256f10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3695-10A (Blood Derived Normal), aliquot TCGA-AA-3695-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56b15d05-fccd-4928-9d29-b0474513fdb7

The open-access MAF lists 168 somatic variants for this specimen: 126 protein-altering or splice-affecting, 40 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 109, Silent 40, Nonsense Mutation 11, Frame Shift Ins 3, Splice Site 3, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 23/30 reads (77%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.3747-2A>G p.X1249_splice | Splice Site (SNP) | VAF 30/78 reads (38%) | catalogued as rs1057517213, COSV99591980; ClinVar: likely pathogenic; called by muse, mutect2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 111/132 reads (84%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 24/43 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SACS | c.6355C>T p.R2119* | Nonsense Mutation (SNP) | VAF 12/94 reads (13%) | catalogued as rs766711286, CM078427, COSV66544501; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.3637C>T p.R1213* (on ENST00000303395 / NM_001202435.3; = p.R1202* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 36/117 reads (31%) | catalogued as rs794726710, CM032366, COSV100320481, COSV57680304; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACKR3 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs371364738, COSV56021632; called by muse, mutect2, varscan2
- ACSS3 | c.1013C>A p.A338E | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs766634948, COSV54097265; called by muse, mutect2, varscan2
- AGO3 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55795648; called by muse, mutect2, varscan2
- AK3 | c.456C>G p.D152E | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV63346954; called by muse, mutect2, varscan2
- AKNAD1 | c.1658C>T p.P553L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs202065262, COSV62201555; called by muse, mutect2, varscan2
- ALPK1 | c.3496T>A p.Y1166N | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51589197; called by muse, mutect2, varscan2
- ARHGEF12 | c.4273C>A p.Q1425K | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.93); catalogued as COSV63106363; called by muse, mutect2, varscan2
- ARID2 | c.4651G>A p.A1551T | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs1161560614, COSV57610699; called by muse, mutect2, varscan2
- ARMCX5 | c.1657C>T p.R553* | Nonsense Mutation (SNP) | VAF 185/605 reads (31%) | catalogued as rs1366416541, COSV55767196; called by muse, mutect2, varscan2
- ARMH3 | c.2062A>G p.I688V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.344); catalogued as rs769383327, COSV53308096; called by muse, mutect2
- BNC1 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61758502; called by muse, mutect2, varscan2
- BRS3 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 62/104 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.168); catalogued as rs376207740, COSV65710669; called by muse, mutect2, varscan2
- CCDC88A | c.1876C>T p.R626* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as rs770918715, COSV55066891; called by muse, mutect2, varscan2
- CCDC9B | c.609dup p.T204Hfs*56 | Frame Shift Ins (INS) | VAF 9/44 reads (20%) | catalogued as rs772754432; called by mutect2, varscan2
- CD163 | c.1493C>A p.T498K | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as COSV63135626; called by muse, mutect2, varscan2
- CDH8 | c.2345G>A p.R782H | Missense Mutation (SNP) | VAF 75/142 reads (53%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs772878546, COSV54867033; called by muse, mutect2, varscan2
- CFAP54 | c.6629T>C p.F2210S | Missense Mutation (SNP) | VAF 136/426 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV100733341; called by muse, mutect2, varscan2
- CHPF2 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as rs752470752, COSV50396239; called by muse, mutect2, varscan2
- CHRM2 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 173/368 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs1432230108, COSV57765651; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHST15 | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 71/151 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs748331919, COSV60560776; called by muse, mutect2, varscan2
- CMYA5 | c.7927C>T p.R2643C | Missense Mutation (SNP) | VAF 104/362 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.676); catalogued as rs199557617; called by muse, mutect2, varscan2
- COL22A1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 114/287 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs779587842, COSV57350270; called by muse, mutect2, varscan2
- COL4A4 | c.4961C>T p.T1654M | Missense Mutation (SNP) | VAF 110/378 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs771066050, COSV61634697; called by muse, mutect2
- CPXM2 | c.1582G>A p.D528N | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as rs1217291885, COSV53867392; called by muse, mutect2, varscan2
- DAB1 | c.1370C>T p.P457L (on ENST00000371231; = p.P424L on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs768694523, COSV64695642; called by muse, mutect2, varscan2
- DMD | c.7309+1G>T p.X2437_splice | Splice Site (SNP) | VAF 39/123 reads (32%) | catalogued as CS982164, COSV58934396; called by muse, mutect2, varscan2
- DNAH5 | c.13089G>T p.M4363I | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as rs1265935718, COSV54241632; called by muse, mutect2, varscan2
- EIF2AK1 | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as rs933969103, COSV52241776; called by muse, mutect2, varscan2
- EPHA8 | c.2863G>A p.G955R | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs990213044, COSV51264100; called by muse, mutect2
- EPHB1 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1281577436, COSV67665617; called by muse, mutect2, varscan2
- FAM135B | c.3925G>A p.V1309M | Missense Mutation (SNP) | VAF 79/207 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52724376; called by muse, mutect2, varscan2
- FAM47A | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.052); catalogued as rs201264239, COSV60497671; called by muse, mutect2, varscan2
- FBP2 | c.624G>T p.K208N | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV64694655, COSV64696130; called by muse, mutect2, varscan2
- FILIP1 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 81/267 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.6); catalogued as rs747071603, COSV52736584; called by muse, mutect2, varscan2
- FNBP1 | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs781146545, COSV63089295; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs200522674; called by muse, mutect2, varscan2
- FRAS1 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs954177790, COSV53630167; called by muse, mutect2, varscan2
- GAD1 | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV60153501; called by muse, mutect2, varscan2
- GBA2 | c.1904C>T p.T635M | Missense Mutation (SNP) | VAF 116/178 reads (65%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs144239565; called by muse, mutect2, varscan2
- GJA8 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV53788670; called by muse, mutect2, varscan2
- GPR158 | c.1802G>A p.R601Q | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs912151372, COSV66277511; called by muse, mutect2, varscan2
- GRIA3 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.875); catalogued as COSV52073348; called by muse, mutect2, varscan2
- GRM1 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs766567009, COSV51198697; called by muse, varscan2
- HCN1 | c.2213T>C p.V738A | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV100301211, COSV57527177; called by muse, mutect2, varscan2
- HYOU1 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.565); catalogued as rs781789542, COSV68215641; called by muse, mutect2, varscan2
- IGSF9 | c.1496C>T p.T499M (on ENST00000368094 / NM_001135050.2; = p.T483M on NM_020789.4) | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs761536687, COSV63641381; called by muse, mutect2, varscan2
- IQGAP2 | c.4426G>A p.A1476T | Missense Mutation (SNP) | VAF 55/101 reads (54%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV57178071; called by muse, mutect2, varscan2
- IRGC | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV54985446; called by muse, mutect2, varscan2
- KIRREL3 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370309110; called by muse, mutect2, varscan2
- KLC4 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as rs201506218, COSV52437929; called by muse, mutect2, varscan2
- KLHL10 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.446); catalogued as rs781939002, COSV53174197; called by muse, mutect2, varscan2
- KRTAP22-1 | c.46G>T p.G16* | Nonsense Mutation (SNP) | VAF 78/164 reads (48%) | catalogued as COSV58182200, COSV58182696; called by muse, mutect2, varscan2
- LIPE | c.1606G>A p.V536M | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs371540113; called by muse, mutect2, varscan2
- LPA | c.679G>A p.V227I | Missense Mutation (SNP) | VAF 22/582 reads (4%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.835); catalogued as rs1200306179; called by muse, mutect2
- LRRK2 | c.3439A>T p.N1147Y | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); catalogued as COSV54163143; called by muse, mutect2, varscan2
- MLLT10 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.567); catalogued as COSV57001138; called by muse, mutect2, varscan2
- NCBP1 | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64317215; called by muse, mutect2, varscan2
- NFIX | c.1435C>T p.R479W (on ENST00000592199 / NM_001365902.3; = p.T429= on NM_002501.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV62179105; called by muse, mutect2, varscan2
- NLRP13 | c.1943A>G p.E648G | Missense Mutation (SNP) | VAF 88/307 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV61623301; called by muse, mutect2, varscan2
- NLRP4 | c.2261C>T p.T754M | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.264); catalogued as rs748656609, COSV56719494; called by muse, mutect2, varscan2
- NPAS2 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs749630318, COSV59560448; called by muse, mutect2, varscan2
- NUDT12 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 57/70 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50092121; called by muse, mutect2, varscan2
- OOEP | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs1031891996, COSV64859430; called by muse, varscan2
- OR10H5 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 36/337 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as rs372682146; called by muse, mutect2, varscan2
- OR2L13 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 106/272 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV63547540, COSV63561899; called by muse, mutect2, varscan2
- OR2T12 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.477); catalogued as COSV58775952; called by muse, mutect2, varscan2
- OR5P2 | c.10C>A p.L4M | Missense Mutation (SNP) | VAF 52/203 reads (26%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.081); catalogued as COSV61491018; called by muse, mutect2
- PCDHB1 | c.1480C>A p.P494T | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.76); catalogued as COSV60632372; called by muse, mutect2, varscan2
- PCDHGA6 | c.1612G>A p.G538R | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs540188136, COSV53997585; called by muse, mutect2, varscan2
- PHF3 | c.835A>G p.K279E | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as COSV50329915; called by muse, mutect2, varscan2
- PJA1 | c.1675G>A p.A559T (on ENST00000361478 / NM_145119.4; = p.A371T on NM_022368.5) | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs1255486840, COSV64053576; called by muse, mutect2, varscan2
- PLXNA4 | c.2872G>T p.D958Y | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as COSV58120202; called by muse, mutect2, varscan2
- PPP1CB | c.160T>G p.L54V | Missense Mutation (SNP) | VAF 75/148 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.045); catalogued as COSV56091480; called by muse, mutect2, varscan2
- PREX2 | c.772G>T p.G258* | Nonsense Mutation (SNP) | VAF 246/531 reads (46%) | catalogued as COSV55789174; called by muse, mutect2, varscan2
- PRKCE | c.736G>A p.G246S | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs746022435, COSV60325436; called by muse, mutect2, varscan2
- PROC | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as rs199469476, CM930611, COSV52167301; called by muse, mutect2, varscan2
- PSG1 | c.34C>A p.R12S | Missense Mutation (SNP) | VAF 27/249 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.106); catalogued as rs143342076, COSV54950507, COSV54954150; called by muse, mutect2, varscan2
- RABGGTA | c.225G>T p.Q75H | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766057450, COSV53771231; called by muse, mutect2, varscan2
- RBFOX1 | c.987C>A p.Y329* | Nonsense Mutation (SNP) | VAF 34/68 reads (50%) | catalogued as COSV60971002; called by muse, varscan2
- RELN | c.6439A>G p.K2147E | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.823); catalogued as COSV59022651; called by muse, mutect2, varscan2
- ROBO2 | c.2912G>A p.G971E | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59927963; called by muse, mutect2, varscan2
- RP1L1 | c.4528G>A p.A1510T | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs775111553, COSV66758244; called by muse, mutect2, varscan2
- SALL2 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58102872; called by muse, mutect2, varscan2
- SEC24B | c.2981G>A p.R994K | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54503791; called by muse, mutect2, varscan2
- SIPA1L1 | c.4993C>T p.P1665S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62170802; called by muse, mutect2
- SLC25A25 | c.1332G>T p.M444I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.06); catalogued as COSV66086751; called by muse, mutect2, varscan2
- SLC35E1 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200335570; called by muse, mutect2, varscan2
- SLC35E1 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV68736205; called by muse, mutect2, varscan2
- SLC4A10 | c.1228C>T p.R410C (on ENST00000446997 / NM_001354461.2; = p.R380C on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 106/175 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs558073659, COSV55769372; called by muse, mutect2, varscan2
- SLC4A11 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.081); catalogued as rs752287261, CM081815, COSV66261292; ClinVar: uncertain significance; called by muse, mutect2
- SLC6A2 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs1353298980, COSV54914945; called by muse, mutect2, varscan2
- SLC9A6 | c.910G>C p.A304P | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.905); catalogued as COSV65788507, COSV65788665; called by muse, mutect2
- SLITRK5 | c.1907C>T p.A636V | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV61524604; called by muse, mutect2, varscan2
- TAS1R2 | c.988G>A p.V330M | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs370333179; called by muse, mutect2, varscan2
- TBL1X | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.094); catalogued as rs370618515, COSV54285007; called by muse, mutect2, varscan2
- TBL1X | c.1726C>T p.R576W | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs746301021, COSV54285030; called by muse, mutect2, varscan2
- TCF7L2 | c.625G>T p.E209* (on ENST00000355995 / NM_001367943.1; = p.E186* on NM_030756.5) | Nonsense Mutation (SNP) | VAF 47/111 reads (42%) | catalogued as COSV53345283; called by muse, mutect2, varscan2
- TENM3 | c.5753C>T p.P1918L | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1480134780, COSV101304825, COSV69303589; called by muse, mutect2, varscan2
- TEX11 | c.2588T>C p.I863T (on ENST00000344304; = p.I848T on NM_031276.3) | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.656); catalogued as COSV100722239; called by muse, mutect2, varscan2
- TEX55 | c.470G>T p.R157I | Missense Mutation (SNP) | VAF 8/252 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV99817820; called by muse, mutect2
- TMCO5A | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.431); catalogued as rs751757881, COSV60465338; called by muse, mutect2, varscan2
- TMTC1 | c.1403G>C p.R468T (on ENST00000539277 / NM_001193451.2; = p.R360T on NM_175861.3) | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99761054; called by muse, mutect2
- TNC | c.4922C>A p.T1641K | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.61); catalogued as COSV60788182; called by muse, mutect2, varscan2
- TP53BP1 | c.272-1G>T p.X91_splice | Splice Site (SNP) | VAF 103/237 reads (43%) | catalogued as COSV55507856, COSV99781543; called by muse, mutect2, varscan2
- TPO | c.2476G>A p.A826T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs781420871, COSV61100326; called by muse, mutect2, varscan2
- TPTE | c.379C>T p.R127C (on ENST00000618007 / NM_199261.4; = p.R109C on NM_199259.4) | Missense Mutation (SNP) | VAF 59/251 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); catalogued as rs148393004; called by muse, mutect2, varscan2
- TRERF1 | c.1472C>T p.S491F | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1476781582, COSV61675468; called by muse, mutect2, varscan2
- TRPC7 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775748277, COSV61452609; called by muse, mutect2, varscan2
- TTLL4 | c.2136C>G p.S712R | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV51438311; called by muse, mutect2, varscan2
- TXLNB | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 80/133 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV64443570; called by muse, mutect2, varscan2
- UNC79 | c.7274A>C p.H2425P (on ENST00000393151 / NM_001346218.2; = p.H2248P on NM_020818.5) | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56401125; called by muse, mutect2, varscan2
- VCAN | c.3842C>T p.T1281M | Missense Mutation (SNP) | VAF 99/208 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.207); catalogued as rs570361402, COSV54099552; called by muse, mutect2, varscan2
- VPS13A | c.1493C>A p.S498Y | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV62434897; called by muse, mutect2, varscan2
- WDR35 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs779530203, COSV55605206; called by muse, mutect2, varscan2
- ZNF160 | c.1918C>T p.R640W | Missense Mutation (SNP) | VAF 99/196 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs568622088, COSV61999644; called by muse, mutect2, varscan2
- ZNF808 | c.2401G>A p.V801M | Missense Mutation (SNP) | VAF 339/620 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.102); catalogued as rs758059403, COSV63120954; called by muse, mutect2, varscan2
- IGKV5-2 | c.334G>T p.D112Y | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (1); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LYRM2 | c.244dup p.T82Nfs*14 | Frame Shift Ins (INS) | VAF 12/30 reads (40%) | called by mutect2, pindel, varscan2
- SERPINI1 | c.390dup p.Y131Ifs*3 | Frame Shift Ins (INS) | VAF 22/81 reads (27%) | called by mutect2, pindel, varscan2
- UGGT2 | c.2534dup p.Y845* | Nonsense Mutation (INS) | VAF 60/137 reads (44%) | called by mutect2, pindel, varscan2
- A2ML1 | c.900C>A p.T300= | Silent (SNP) | VAF 24/107 reads (22%) | catalogued as rs761769559, COSV55295338, COSV55298371; called by muse, mutect2, varscan2
- ARHGAP20 | c.138C>T p.S46= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as rs150049858; called by muse, mutect2, varscan2
- CGNL1 | c.256C>T p.L86= | Silent (SNP) | VAF 73/184 reads (40%) | catalogued as COSV55572284; called by muse, mutect2, varscan2
- CHRNA5 | c.552T>C p.C184= | Silent (SNP) | VAF 134/347 reads (39%) | catalogued as COSV55139712; called by muse, mutect2, varscan2
- CREBBP | c.2178C>T p.P726= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as rs151083156, COSV99268539; called by muse, mutect2, varscan2
- CUBN | c.6174C>A p.I2058= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as COSV64722666; called by muse, mutect2, varscan2
- DDX60 | c.1665G>A p.V555= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV67098205; called by muse, mutect2, varscan2
- DNAH10 | c.8838G>A p.A2946= (on ENST00000409039; = p.A2885= on NM_207437.3) | Silent (SNP) | VAF 61/65 reads (94%) | catalogued as rs374138803; called by muse, mutect2, varscan2
- ERBB4 | c.1440A>T p.T480= | Silent (SNP) | VAF 53/174 reads (30%) | catalogued as COSV53562122; called by muse, mutect2, varscan2
- EXOC3L2 | c.1218C>T p.L406= | Silent (SNP) | VAF 16/22 reads (73%) | catalogued as COSV52973976; called by muse, mutect2, varscan2
- FLRT2 | c.1191T>A p.P397= | Silent (SNP) | VAF 17/147 reads (12%) | catalogued as COSV58146999; called by muse, mutect2, varscan2
- FOLR1 | c.393C>T p.N131= | Silent (SNP) | VAF 38/120 reads (32%) | catalogued as rs61735636, COSV56616714; ClinVar: likely benign; called by muse, mutect2, varscan2
- HOOK2 | c.1680G>A p.K560= | Silent (SNP) | VAF 30/52 reads (58%) | catalogued as COSV53403240; called by muse, mutect2, varscan2
- IL9R | c.126C>G p.V42= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV54901225; called by muse, mutect2, varscan2
- KCNA4 | c.108C>G p.S36= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV60252139, COSV60254388; called by muse, mutect2, varscan2
- KCNK2 | c.183G>A p.T61= (on ENST00000444842 / NM_001017425.3; = p.T46= on NM_014217.4) | Silent (SNP) | VAF 49/102 reads (48%) | catalogued as rs375389536, COSV101221759, COSV67208352; called by muse, mutect2, varscan2
- KDR | c.1563G>A p.A521= | Silent (SNP) | VAF 89/222 reads (40%) | catalogued as rs200769864, COSV55771803; called by muse, mutect2, varscan2
- KLHL4 | c.801C>G p.V267= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV64145827; called by muse, mutect2, varscan2
- KRT85 | c.540G>T p.R180= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as COSV57737696; called by muse, mutect2, varscan2
- LONRF2 | c.1893G>A p.A631= | Silent (SNP) | VAF 122/184 reads (66%) | catalogued as rs763917753, COSV66541663; called by muse, mutect2, varscan2
- LRP1B | c.4128C>A p.A1376= | Silent (SNP) | VAF 51/92 reads (55%) | catalogued as COSV67253349; called by muse, mutect2, varscan2
- MAGEE1 | c.999G>A p.P333= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV63911360; called by muse, mutect2, varscan2
- NRCAM | c.1332C>T p.N444= (on ENST00000379028 / NM_001371124.1; = p.N438= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 43/95 reads (45%) | catalogued as rs968424772, COSV61043856; called by muse, mutect2, varscan2
- NRK | c.1881A>T p.L627= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV54602469; called by muse, mutect2
- OGA | c.909C>T p.L303= | Silent (SNP) | VAF 46/112 reads (41%) | catalogued as rs775392805, COSV63382609; called by muse, mutect2, varscan2
- OOEP | c.291C>T p.F97= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs1370736514, COSV64859312; called by muse, varscan2
- PCDHA12 | c.213C>T p.H71= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as rs563250653, COSV56530222; called by muse, mutect2, varscan2
- PCDHB1 | c.1122G>A p.R374= | Silent (SNP) | VAF 39/119 reads (33%) | catalogued as COSV60632362; called by muse, mutect2, varscan2
- PCDHGB3 | c.1887G>A p.A629= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV53978095; called by muse, mutect2, varscan2
- PGK1 | c.864T>C p.T288= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as COSV64832461; called by muse, mutect2, varscan2
- PKHD1L1 | c.229T>C p.L77= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV101006844; called by muse, mutect2
- POU2F2 | c.1080G>A p.A360= (on ENST00000526816 / NM_001207025.3; = p.A344= on NM_002698.5) | Silent (SNP) | VAF 9/12 reads (75%) | catalogued as rs192872020, COSV60760898; called by muse, mutect2, varscan2
- PSMD5 | c.294T>A p.S98= | Silent (SNP) | VAF 39/153 reads (25%) | catalogued as COSV52961475; called by muse, mutect2, varscan2
- SERPINB11 | c.636G>A p.V212= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV66957501; called by muse, varscan2
- SLC26A3 | c.1662G>A p.R554= | Silent (SNP) | VAF 42/222 reads (19%) | catalogued as COSV60641609; called by muse, mutect2, varscan2
- SSPN | c.357T>C p.F119= | Silent (SNP) | VAF 40/175 reads (23%) | catalogued as COSV54380674, COSV54381799; called by muse, mutect2, varscan2
- TENM2 | c.2697G>T p.V899= (on ENST00000518659 / NM_001122679.2; = p.V667= on NM_001080428.3) | Silent (SNP) | VAF 21/35 reads (60%) | catalogued as rs753326451, COSV69137155; called by muse, mutect2, varscan2
- TMTC1 | c.1158C>T p.G386= (on ENST00000539277 / NM_001193451.2; = p.G278= on NM_175861.3) | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV55488675; called by muse, mutect2, varscan2
- USP36 | c.216C>A p.R72= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV61753075; called by muse, mutect2, varscan2
- ZBTB40 | c.855T>C p.G285= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as rs545224543, COSV65146086; called by muse, mutect2, varscan2
- NRG1 | c.502+31396G>A | Intron (SNP) | VAF 35/183 reads (19%) | catalogued as rs766079837, COSV55151686; called by muse, mutect2, varscan2
- SSPOP | n.15674C>T | RNA (SNP) | VAF 15/34 reads (44%) | catalogued as rs369846163; called by muse, mutect2, varscan2
